Gene-level copy-number profile of tumor specimen TCGA-3G-AB0T-01A from TCGA case TCGA-3G-AB0T, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Thymoma, type B1, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 45.8 years (16,728 days).
Specimen TCGA-3G-AB0T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-THYM.519aa72c-c648-4539-a28c-067f335be55c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-3G-AB0T-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/abf324a1-fa20-4534-83ed-595b5f4c1bc7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,610; copy number 2: 57,174; copy number 3: 34.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-3G-AB0T-01A-11D-A422-01): tumor purity 0.32, ploidy 2.05, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 223. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
